Somatic mutation profile of tumor specimen TARGET-20-PASYRE-03A (aliquot TARGET-20-PASYRE-03A-01D) from TARGET case TARGET-20-PASYRE, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.2 years (4,830 days).
Specimen TARGET-20-PASYRE-03A: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 163c16bd-0c09-41ad-b3b9-2565314d7867.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASYRE-14A (Bone Marrow Normal), aliquot TARGET-20-PASYRE-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f71a1e3-18a3-4fb6-b741-5f8186bc5ead

The open-access MAF lists 2 somatic variants for this specimen: 2 protein-altering or splice-affecting.
By variant classification: Splice Site 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLT3 | c.1781T>A p.F594Y | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.375); catalogued as COSV54052730; called by muse, mutect2, varscan2
- PTPRC | c.2938+1G>A p.X980_splice | Splice Site (SNP) | VAF 3/36 reads (8%) | called by muse, mutect2
